Somatic mutation profile of tumor specimen TCGA-V1-A9ZK-01A (aliquot TCGA-V1-A9ZK-01A-11D-A41K-08) from TCGA case TCGA-V1-A9ZK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59607357-a9b9-4724-81b1-e060e3e315b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9ZK-10A (Blood Derived Normal), aliquot TCGA-V1-A9ZK-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8e9cb12-2ec2-4380-9450-997bf9596623

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15640C>T p.R5214C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123728, CM114916, COSV56407525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPOP | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs193921065, COSV61652814, COSV61652918; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C1S | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.175); catalogued as rs1296400600, COSV61072070; called by muse, mutect2
- ERMARD | c.520A>C p.K174Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV100824747; called by muse, mutect2, varscan2
- FAM193B | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs563761633, COSV100286399; called by muse, mutect2, varscan2
- INPPL1 | c.2653C>T p.L885F | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99995891; called by muse, mutect2, varscan2
- KMT2D | c.15641G>T p.R5214L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; called by muse, mutect2, varscan2
- MACF1 | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | catalogued as COSV100482699; called by muse, mutect2, varscan2
- MYO9A | c.7490A>C p.K2497T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100612727; called by muse, mutect2, varscan2
- NUDT12 | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100048039; called by muse, mutect2
- PRKDC | c.11874G>T p.L3958F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038662; called by muse, mutect2, varscan2
- RPTOR | c.1462C>G p.R488G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100155269, COSV60815913; called by muse, mutect2, varscan2
- SNX13 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs747423629, COSV101296789, COSV68068850; called by mutect2, varscan2
- TENM2 | c.2247C>A p.C749* (on ENST00000518659 / NM_001122679.2; = p.C517* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101317942; called by muse, mutect2
- UBAP1 | c.1153C>A p.L385M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99902866; called by muse, mutect2, varscan2
- GDAP2 | c.1164_1173del p.L388Ffs*4 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- OR8A1 | c.621del p.I207Mfs*5 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1341T>G p.Y447* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- GLCE | c.654A>T p.G218= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99962105; called by muse, mutect2, varscan2
- KCNC4 | c.1710G>A p.E570= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1408101913, COSV100873574; called by muse, mutect2, varscan2
- MED15 | c.1173C>G p.A391= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV99487388; called by muse, mutect2
- EIF4G1 | c.-91-104C>G | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs369864792, COSV100071510; called by muse, mutect2, varscan2
- SNORD3B-2 | n.212A>G | RNA (SNP) | VAF 28/414 reads (7%) | catalogued as rs765302938; called by muse, mutect2
